HCMI case HCM-CSHL-0861-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/561a4c46-ca78-444f-8346-c30daa041d27

Demographics
Sex at birth: male; Year of birth: 1954; Vital status: Alive.

Diagnoses (2)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 65.8 years (24,023 days); AJCC staging edition: 8th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G2; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Prior treatment: No; Sites of involvement: Lymph node, NOS.
   Pathology details: Peripancreatic lymph nodes positive: 4 or More; Peripancreatic lymph nodes tested: 34.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -6 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 45 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/6; ICD-10 code: C77.2; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 65.8 years (24,023 days).
   Pathology details: Peripancreatic lymph nodes positive: 4 or More; Peripancreatic lymph nodes tested: 34.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 0 days.
- Days to follow up: 259 days; Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 65.

Molecular and laboratory tests
- CA19-9: 180.
- CEA: 10 ng/mL; Blood test normal range upper: 4.
- CEA: 7 ng/mL; Blood test normal range upper: 4.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Diabetes, NOS; Diabetes treatment type: Biguanide.
- Timepoint category: Initial Diagnosis; Weight: 62 kg; Height: 165 cm; BMI: 23.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Alcohol intensity: Non-Drinker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample HCM-CSHL-0861-C25-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0861-C25-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
